Surgical pathology report (de-identified scan), TCGA case TCGA-QK-AA3J, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Emory University - Winship Cancer Inst., specimen TCGA-QK-AA3J-01A (Primary Tumor).

[page 1 of 2]
Document Type:
Document Date:
Document Status:
Document Title:
Performed By:
Verified By:
Encounter info:

Anat Path Reports

ICB-0-3
Carcinoma, squamous cell, basaloid
Site: ^{USF} Larynx NOS C32.9
^{path} Arytenoid cartilage C32.3
8083/3
7/3/11/14

*** Final Report ***

Patient Name:

Acc #:

MRN:

DOB:

Head and Neck

Location:

Gender:

M

Collected:

Client:

Received:

Submitting Phys:

Reported:

Final Surgical Pathology Report

Final Pathologic Diagnosis

ARYTENOID, RIGHT, BIOPSY:

- INVASIVE SQUAMOUS CELL CARCINOMA, POORLY DIFFERENTIATED WITH BASALOID FEATURES.

Electronically Signed by

Clinical History

Panendoscopy.

Specimen(s) Received

A: Right arytenoid

Gross Description

The specimen is received fresh for frozen section diagnosis labeled with the patient's name, medical record number and "panendoscopy" on the container and consists of multiple pink-red soft tissue fragments, collectively 1.0 x 0.8 x 0.2 cm. Approximately 2/3 of the specimen is submitted for frozen section diagnosis in cassette A1FS. The remaining specimen is submitted to tissue procurement services. (Dictated by

Intraoperative Consult Diagnosis

A1FS (2 slides): (FROZEN SECTION): invasive carcinoma, consistent with squamous cell carcinoma.
Frozen section results were communicated to the surgical team and were repeated back by
on

[page 2 of 2]
Pathologist:

Criteria	bw 1/7/14	Yes	No
Dual/Synchronous Primary	NOTED		✓

Source: NCI Genomic Data Commons file 8db541fa-5350-425d-93ca-6f4cd30ef6bc (TCGA-QK-AA3J.94EF76C0-AEB3-472D-B4E0-CB7C48EDF816.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).